Somatic mutation profile of tumor specimen TARGET-15-SJMPAL040025-09A.1 (aliquot TARGET-15-SJMPAL040025-09A.1-01D) from TARGET case TARGET-15-SJMPAL040025, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.1 years (3,319 days).
Specimen TARGET-15-SJMPAL040025-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59298592-4305-4bb6-b69b-4bfb9274f391.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL040025-14A.1 (Bone Marrow Normal), aliquot TARGET-15-SJMPAL040025-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1ae11e59-bb6d-488f-98f6-c527d0775d51

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GHDC | c.60G>T p.R20S | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2
- HGS | c.1462C>T p.R488C | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHV1-45 | chr14:106506994 TGTAT>GGGGGGAG | Missense Mutation (INS) | VAF 30/77 reads (39%) | called by muse*, pindel
- INCA1 | c.6G>T p.Q2H | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- RBM26 | c.1103G>T p.G368V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); called by muse, mutect2
- TNFRSF25 | c.1156C>T p.Q386* | Nonsense Mutation (SNP) | VAF 16/33 reads (48%) | called by muse, mutect2, varscan2
- ZMIZ1 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- LRRC9 | c.1194C>A p.G398= | Silent (SNP) | VAF 3/25 reads (12%) | called by muse, mutect2
- TNFRSF25 | c.1155G>A p.Q385= | Silent (SNP) | VAF 16/34 reads (47%) | called by muse, mutect2, varscan2
- ZNF831 | c.1026C>G p.T342= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs939365835, COSV100926340; called by muse, mutect2
- SHKBP1 | c.140+14C>A | Intron (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
